Somatic mutation profile of tumor specimen TCGA-D7-8575-01A (aliquot TCGA-D7-8575-01A-11D-2340-08) from TCGA case TCGA-D7-8575, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 75.9 years (27,712 days).
Specimen TCGA-D7-8575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d962b3a-0f8f-4e83-b7f3-bf651513970b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8575-10A (Blood Derived Normal), aliquot TCGA-D7-8575-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e656a1c3-6476-4803-a0eb-1a2be7b3dc82

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 5, Frame Shift Ins 3, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV59388573; called by muse, mutect2, varscan2
- ABCG5 | c.403-2A>C p.X135_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as COSV53211614; called by muse, mutect2, varscan2
- ARHGDIG | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs751743144, COSV51988995; called by muse, mutect2, varscan2
- C17orf75 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.402); catalogued as rs368558604; called by muse, mutect2, varscan2
- CADM3 | c.235C>T p.R79* (on ENST00000368125 / NM_001127173.3; = p.R113* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV63686065; called by muse, mutect2, varscan2
- CALN1 | c.334G>A p.D112N (on ENST00000329008 / NM_001017440.3; = p.D154N on NM_031468.4) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs748456626, COSV61121606; called by muse, mutect2, varscan2
- COL3A1 | c.1946C>G p.P649R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100482857, COSV58591104; called by muse, mutect2, varscan2
- CREBBP | c.4900G>A p.V1634M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52121588; called by muse, mutect2, varscan2
- DNAAF1 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58987323; called by muse, mutect2, varscan2
- DOCK2 | c.1886T>C p.L629P | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.692); catalogued as COSV56966937; called by muse, mutect2, varscan2
- ERAP1 | c.2602T>G p.S868A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57091343, COSV99701244; called by muse, mutect2, varscan2
- ERN1 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as COSV70502892; called by muse, mutect2, varscan2
- FAT2 | c.10945C>T p.R3649W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142359154; called by muse, mutect2, varscan2
- GPRASP1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 57/89 reads (64%) | catalogued as COSV100851110, COSV64355581; called by muse, mutect2, varscan2
- HGF | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768451705, COSV55947351, COSV55955898; called by muse, mutect2, varscan2
- KDM2A | c.3047A>G p.D1016G | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58190301; called by muse, mutect2, varscan2
- KRT24 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV52879518, COSV52879937; called by muse, mutect2, varscan2
- MAP1B | c.6637C>T p.R2213C | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs573728562, COSV57101235; called by muse, mutect2, varscan2
- MCOLN1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs886054695, COSV51176962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEST | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 37/71 reads (52%) | catalogued as COSV56228948; called by muse, mutect2, varscan2
- MICAL1 | c.1483_1485del p.N495del | In Frame Del (DEL) | VAF 30/120 reads (25%) | catalogued as rs766443242; called by pindel, varscan2
- MSR1 | c.1292T>G p.I431S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV50516219; called by muse, mutect2, varscan2
- NTRK3 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as COSV58128384; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OVCH1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771073063, COSV58964797; called by muse, mutect2, varscan2
- PCDH11X | c.1257G>C p.E419D | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53477781; called by muse, mutect2, varscan2
- PCDH11Y | c.2446G>C p.E816Q (on ENST00000400457 / NM_032973.2; = p.E805Q on NM_032971.3) | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV53076181, COSV53083781; called by muse, mutect2, varscan2
- PTGFR | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.041); catalogued as COSV66115553, COSV66115721; called by muse, mutect2, varscan2
- PTK2B | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57759442; called by muse, mutect2, varscan2
- RBM15 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63923768; called by muse, mutect2, varscan2
- SAE1 | c.794A>T p.D265V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54296512; called by muse, mutect2, varscan2
- SH3RF2 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs762910007, COSV63039389; called by muse, mutect2, varscan2
- SNAP91 | c.2108C>A p.T703K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV52126033; called by muse, mutect2, varscan2
- TCTN1 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs1410574688, COSV66541598; called by muse, mutect2, varscan2
- TINAGL1 | c.172C>G p.R58G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54699334; called by muse, mutect2, varscan2
- YTHDC2 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50744789; called by muse, mutect2
- ZNF408 | c.1009C>G p.R337G | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61238525; called by muse, mutect2, varscan2
- ATM | c.5231dup p.T1745Dfs*4 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- OR10G3 | c.68_72dup p.T25* | Nonsense Mutation (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- SP7 | c.383_386dup p.D130Sfs*48 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- ZSWIM5 | c.2425dup p.S809Ffs*48 | Frame Shift Ins (INS) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- C9orf43 | c.1164T>C p.S388= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV55913049; called by muse, mutect2, varscan2
- CARNS1 | c.1728C>T p.S576= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV57051510; called by muse, mutect2, varscan2
- DNAH9 | c.7999C>T p.L2667= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs1205478901, COSV52357270; called by muse, mutect2, varscan2
- GARRE1 | c.1344T>A p.V448= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV55100825; called by muse, mutect2, varscan2
- IKZF1 | c.813C>T p.V271= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs375111826; called by muse, mutect2, varscan2
- MAGEA12 | c.789C>A p.G263= | Silent (SNP) | VAF 87/128 reads (68%) | catalogued as COSV63294946; called by muse, mutect2, varscan2
- QSOX2 | c.2073C>G p.V691= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV62394467; called by muse, mutect2, varscan2
- TRMT112 | c.117C>T p.P39= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV50006262; called by muse, mutect2, varscan2
- USP35 | c.2796G>A p.E932= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV60868906; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-468A>G | Intron (SNP) | VAF 21/69 reads (30%) | catalogued as rs376908784; called by muse, mutect2, varscan2
